Somatic mutation profile of tumor specimen 0DTHM0 from CCDI case PBCJBC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.1 years (2,955 days).
Specimen 0DTHM0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 125fd0b6-2463-46f9-a3ac-8b55bda28f01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTHMC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16fdee88-62c7-4ea5-8270-20d01c80cc60

The open-access MAF lists 16 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 4, Intron 2, Silent 2, 3'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 186/1238 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs80357446, CM041685, CM101977; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OR8K5 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 102/1702 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs377710232; called by muse, mutect2
- TBC1D31 | c.721T>C p.W241R | Missense Mutation (SNP) | VAF 120/1687 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54871283; called by muse, mutect2
- PBXIP1 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 56/831 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2
- TCF3 | c.757_767del p.S253Gfs*92 | Frame Shift Del (DEL) | VAF 54/332 reads (16%) | called by mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 44/1628 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- AGTR1 | c.471C>T p.G157= | Silent (SNP) | VAF 467/1967 reads (24%) | called by muse, mutect2, varscan2
- MEIOB | c.1161C>T p.G387= | Silent (SNP) | VAF 30/852 reads (4%) | called by muse, mutect2
- ARHGEF3 | c.97-1375A>C | Intron (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- C5orf47 | c.-1G>A | 5'UTR (SNP) | VAF 42/772 reads (5%) | catalogued as rs779833133, COSV60864974; called by muse, mutect2
- FAP | c.1815-34T>A | Intron (SNP) | VAF 18/718 reads (3%) | called by muse, mutect2
- GRB14 | c.-90G>A | 5'UTR (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2
- RBBP8NL | c.*4G>T | 3'UTR (SNP) | VAF 30/561 reads (5%) | called by muse, mutect2
- RGS10 | c.*23C>A | 3'UTR (SNP) | VAF 61/369 reads (17%) | called by muse, mutect2, varscan2
- XKR6 | c.-56C>A | 5'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2
- XKR6 | c.-57T>A | 5'UTR (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2
